Somatic mutation profile of tumor specimen C3N-01858-01 (aliquot CPT0163840006) from CPTAC case C3N-01858, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 62.9 years (22,982 days).
Specimen C3N-01858-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 345b4d19-7b02-4bf1-94e1-3004f18f355a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01858-31 (Blood Derived Normal), aliquot CPT0163900002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3bdac173-1716-4eb1-8953-c50d99b85994

The open-access MAF lists 1,752 somatic variants for this specimen: 1,173 protein-altering or splice-affecting, 329 silent, 250 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 865, Silent 329, Frame Shift Del 199, Intron 129, 3'UTR 38, Nonsense Mutation 35, RNA 34, Frame Shift Ins 33, 5'UTR 21, 5'Flank 18, Splice Site 18, Splice Region 11.

Variants (750 of 1,752; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAT1 | c.890C>T p.T297M | Missense Mutation (SNP) | VAF 39/215 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs886041122, CM950007, COSV56187962; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASXL1 | c.1934del p.G645Vfs*58 | Frame Shift Del (DEL) | VAF 26/130 reads (20%) | hotspot (GDC flag); catalogued as rs750318549; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BSCL2 | c.782dup p.I262Hfs*12 | Frame Shift Ins (INS) | VAF 44/311 reads (14%) | catalogued as rs749890533; ClinVar: pathogenic; called by mutect2, varscan2
- FBN1 | c.2645C>T p.A882V | Missense Mutation (SNP) | VAF 102/551 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs794728195, CM042039, COSV57322094; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MAGEL2 | c.1996dup p.Q666Pfs*47 | Frame Shift Ins (INS) | VAF 14/60 reads (23%) | catalogued as rs770374710; ClinVar: pathogenic; called by mutect2, varscan2
- MSL3 | c.1372C>T p.R458* (on ENST00000312196 / NM_078629.4; = p.R292* on NM_006800.4) | Nonsense Mutation (SNP) | VAF 40/104 reads (38%) | catalogued as rs1555907620, COSV56495389; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MYO15A | c.419dup p.F141Vfs*87 | Frame Shift Ins (INS) | VAF 72/551 reads (13%) | catalogued as rs750130520; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- SETD2 | c.4715+1G>A p.X1572_splice | Splice Site (SNP) | VAF 7/39 reads (18%) | hotspot (GDC flag); catalogued as COSV57431126, COSV57439397; called by muse, mutect2, varscan2
- SMARCB1 | c.463C>T p.R155* (on ENST00000263121; = p.R201* on NM_003073.5) | Nonsense Mutation (SNP) | VAF 112/596 reads (19%) | catalogued as rs1555877286, CM992975, COSV54093216; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STK11 | c.842del p.P281Rfs*6 | Frame Shift Del (DEL) | VAF 17/63 reads (27%) | catalogued as rs121913321; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.673-2A>T p.X225_splice | Splice Site (SNP) | VAF 75/405 reads (19%) | hotspot (GDC flag); catalogued as CS109519, COSV52669186, COSV52682653, COSV52687702; called by muse, mutect2, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 75/425 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ZNF469 | c.10248del p.R3417Gfs*56 (on ENST00000437464; = p.R3445Gfs*56 on NM_001367624.2) | Frame Shift Del (DEL) | VAF 16/130 reads (12%) | catalogued as rs764470052, COSV99081573; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- A2M | c.3322G>A p.A1108T | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs746089621, COSV59387039; called by muse, mutect2, varscan2
- ABCC8 | c.1603G>A p.A535T | Missense Mutation (SNP) | VAF 77/453 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1393328052; called by muse, mutect2, varscan2
- AC008397.2 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV62747714; called by muse, mutect2, varscan2
- ACSS1 | c.1159G>A p.A387T | Missense Mutation (SNP) | VAF 42/292 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs377038551; called by muse, mutect2, varscan2
- ACSS2 | c.806del p.P269Qfs*69 | Frame Shift Del (DEL) | VAF 23/142 reads (16%) | catalogued as rs745681981, COSV53623223; called by mutect2, pindel, varscan2
- ADAM11 | c.356G>T p.R119L | Missense Mutation (SNP) | VAF 39/246 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV99567681; called by muse, mutect2, varscan2
- ADAM8 | c.838A>G p.T280A | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs779633232; called by muse, varscan2
- ADGRG5 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 80/397 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs201549132, COSV61083297; called by muse, mutect2, varscan2
- ADGRG6 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs377682546; called by muse, mutect2, varscan2
- ADSL | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 97/566 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV53407861, COSV99342574; called by muse, mutect2, varscan2
- AGBL2 | c.2278C>T p.R760* | Nonsense Mutation (SNP) | VAF 17/125 reads (14%) | catalogued as rs377064786; called by muse, mutect2, varscan2
- AGK | c.732G>A p.W244* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as COSV100814712, COSV62595057; called by muse, mutect2, varscan2
- AHCTF1 | c.4045T>C p.S1349P (on ENST00000366508; = p.S1323P on NM_015446.5) | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as rs757335600; called by muse, mutect2, varscan2
- AJM1 | c.994C>A p.R332S | Missense Mutation (SNP) | VAF 32/487 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as rs1325390224, COSV56032008; called by muse, mutect2
- AKNA | c.4283G>A p.R1428H | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs776409662, COSV56339842, COSV99034382; called by muse, mutect2, varscan2
- ALDH1A3 | c.739C>T p.H247Y | Missense Mutation (SNP) | VAF 25/222 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs754376404; called by muse, mutect2, varscan2
- ALDH1B1 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs369090946, COSV66619607; called by muse, mutect2, varscan2
- ALDH5A1 | c.1565A>G p.D522G | Missense Mutation (SNP) | VAF 40/235 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs777938693; called by muse, mutect2, varscan2
- ALG1 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 69/469 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.765); catalogued as rs893026064; called by muse, mutect2, varscan2
- ALKBH3 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs202134415; called by muse, mutect2, varscan2
- ALPK2 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as rs1568092203, COSV64493335; called by muse, mutect2, varscan2
- ALS2 | c.3394C>T p.R1132C | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs149670991, COSV51885571; called by muse, mutect2, varscan2
- ANGPT4 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 47/285 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs150174277, COSV67921961; called by muse, mutect2, varscan2
- ANKFY1 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs766157391; called by muse, mutect2, varscan2
- ANKLE2 | c.1354-8del | Splice Region (DEL) | VAF 13/71 reads (18%) | catalogued as rs749179890; called by mutect2, varscan2
- ANKLE2 | c.741G>C p.E247D | Missense Mutation (SNP) | VAF 41/245 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV61712026; called by muse, mutect2, varscan2
- ANKS1A | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 52/292 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs780744564; called by muse, mutect2, varscan2
- ANO2 | c.1001C>T p.A334V (on ENST00000356134 / NM_001278597.3; = p.A338V on NM_001278596.3) | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1469255109, COSV100501545; called by muse, mutect2, varscan2
- AP002512.3 | c.610T>C p.C204R | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1565146517; called by muse, mutect2, varscan2
- AP1G2 | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs748127582, COSV55338027; called by muse, mutect2, varscan2
- APC | c.2662G>A p.A888T | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.116); catalogued as COSV57373516; called by muse, mutect2, varscan2
- APOB | c.3052G>A p.A1018T | Missense Mutation (SNP) | VAF 53/299 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs149357946, COSV51953773; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 34/194 reads (18%) | catalogued as rs772728725, COSV54066450; called by mutect2, varscan2
- ARHGAP26 | c.155-1G>A p.X52_splice | Splice Site (SNP) | VAF 10/113 reads (9%) | catalogued as COSV99190978; called by muse, mutect2
- ARHGAP39 | c.1664C>T p.A555V | Missense Mutation (SNP) | VAF 28/240 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.148); catalogued as COSV52773253; called by muse, mutect2, varscan2
- ARHGEF10 | c.649G>A p.A217T (on ENST00000398564; = p.A192T on NM_014629.4) | Missense Mutation (SNP) | VAF 70/515 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.012); catalogued as rs779899466, COSV50649026; called by muse, mutect2, varscan2
- ARID3B | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs368986093; called by muse, mutect2
- ARMC9 | c.1029C>T p.R343= | Splice Region (SNP) | VAF 18/220 reads (8%) | catalogued as rs1481102945; called by muse, mutect2
- ASB1 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 43/229 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs766226125, COSV99223479; called by muse, mutect2, varscan2
- ASPM | c.2929C>T p.R977C | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750015604, COSV54130724; called by muse, mutect2, varscan2
- ASPSCR1 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 37/213 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1300405225, COSV99049246; called by muse, mutect2
- ATF5 | c.109del p.L37Wfs*31 | Frame Shift Del (DEL) | VAF 14/102 reads (14%) | catalogued as rs768611141; called by mutect2, pindel, varscan2
- ATP11A | c.1798C>T p.R600C | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.67); catalogued as COSV99370525; called by muse, varscan2
- ATP12A | c.342del p.F115Sfs*28 | Frame Shift Del (DEL) | VAF 52/174 reads (30%) | catalogued as rs35191129; called by mutect2, pindel, varscan2
- ATP13A1 | c.2216C>T p.A739V | Missense Mutation (SNP) | VAF 49/236 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1326686011, COSV52285352; called by muse, mutect2, varscan2
- ATP2B3 | c.2075G>A p.R692Q | Missense Mutation (SNP) | VAF 69/189 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as rs143426870; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1185del p.Y396Tfs*12 | Frame Shift Del (DEL) | VAF 24/171 reads (14%) | catalogued as rs566440675, CD023240; called by mutect2, pindel, varscan2
- ATP6V1B1 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 92/584 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as rs782497280, COSV99314343; called by muse, mutect2, varscan2
- ATP6V1B2 | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs577956380, COSV99369247; called by muse, mutect2, varscan2
- ATP8A2 | c.2467G>A p.A823T | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54948649; called by muse, mutect2, varscan2
- ATP9A | c.1390G>A p.A464T | Missense Mutation (SNP) | VAF 78/499 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1448351539, COSV58768944; called by muse, mutect2, varscan2
- ATXN1 | c.1576G>A p.A526T | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs757466549; called by muse, mutect2, varscan2
- BAHCC1 | c.7789C>T p.R2597C | Missense Mutation (SNP) | VAF 33/866 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV57033110; called by muse, mutect2
- BCAT2 | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 44/312 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374377249, COSV60272888; called by muse, mutect2, varscan2
- BCKDK | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 34/221 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as rs1054014743; called by muse, mutect2, varscan2
- BCOR | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60701872; called by muse, mutect2, varscan2
- BEST3 | c.1711G>A p.A571T | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs140412369, COSV58303591; called by muse, mutect2, varscan2
- BOC | c.2080G>A p.A694T | Missense Mutation (SNP) | VAF 53/327 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs759707512; called by muse, mutect2, varscan2
- BPIFB2 | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 35/301 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.571); catalogued as rs199997957; called by muse, mutect2, varscan2
- BRD8 | c.2250-3del | Splice Region (DEL) | VAF 10/38 reads (26%) | catalogued as rs749043197; called by mutect2, varscan2
- BRSK1 | c.1135del p.R379Gfs*9 | Frame Shift Del (DEL) | VAF 14/45 reads (31%) | catalogued as rs746043904, COSV58665984; called by mutect2, varscan2
- BTBD9 | c.1440G>A p.M480I | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV100022744; called by muse, mutect2, varscan2
- BZW2 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 54/316 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as rs1292741642; called by muse, mutect2, varscan2
- CACNA1C | c.5897G>A p.R1966Q (on ENST00000399634 / NM_001167625.1; = p.R1895Q on NM_000719.7) | Missense Mutation (SNP) | VAF 93/572 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.921); catalogued as rs753954220, COSV59720154; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA2D3 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1265001369, COSV55587238; called by muse, mutect2, varscan2
- CALHM2 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.322); catalogued as rs777338270; called by muse, mutect2, varscan2
- CAMK2B | c.893G>T p.R298I | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99322591; called by muse, mutect2, varscan2
- CAPN10 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 49/276 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.348); catalogued as rs770272925, COSV54375207; called by muse, mutect2, varscan2
- CAPRIN1 | c.1919G>A p.R640H | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV100403767, COSV58220917; called by muse, mutect2, varscan2
- CASP8AP2 | c.3390del p.K1130Nfs*6 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | catalogued as rs768812342; called by mutect2, varscan2
- CATSPER1 | c.1017del p.G340Afs*14 | Frame Shift Del (DEL) | VAF 52/378 reads (14%) | catalogued as COSV100376228; called by mutect2, pindel, varscan2
- CATSPER1 | c.169T>C p.S57P | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV100375612; called by muse, mutect2, varscan2
- CBLN2 | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.03); catalogued as rs1240629146; called by muse, mutect2, varscan2
- CCDC136 | c.3143del p.K1048Sfs*3 | Frame Shift Del (DEL) | VAF 40/202 reads (20%) | catalogued as rs761237807; called by mutect2, pindel, varscan2
- CCDC158 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.829); catalogued as rs544942791; called by muse, varscan2
- CCDC160 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100892124; called by muse, mutect2, varscan2
- CCDC180 | c.4070G>T p.R1357L | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs143232808, COSV100827182, COSV63836897; called by muse, mutect2, varscan2
- CCDC65 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs543578641, COSV57194987; called by muse, mutect2, varscan2
- CD84 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs765929958, COSV60867344; called by muse, mutect2
- CDAN1 | c.2915A>C p.K972T | Missense Mutation (SNP) | VAF 99/533 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1381239769; called by muse, mutect2, varscan2
- CDC40 | c.870C>T p.G290= | Splice Region (SNP) | VAF 24/167 reads (14%) | catalogued as rs559751620, COSV57010223; called by muse, mutect2, varscan2
- CDC42BPB | c.2596C>T p.R866C | Missense Mutation (SNP) | VAF 45/227 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs781307670, COSV63476797; called by muse, mutect2, varscan2
- CDCA2 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.237); catalogued as rs958566460, COSV57944592; called by muse, mutect2
- CDH23 | c.3778G>A p.E1260K | Missense Mutation (SNP) | VAF 34/187 reads (18%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.655); catalogued as rs752118060, COSV56456230, COSV56456628; called by muse, mutect2, varscan2
- CDHR2 | c.3871G>A p.A1291T | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs749523542, COSV56137105; called by muse, mutect2, varscan2
- CDHR5 | c.1781G>A p.G594D (on ENST00000358353 / NM_001171968.2; = p.G600D on NM_021924.5) | Missense Mutation (SNP) | VAF 22/411 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as rs1257162481, COSV57644584; called by muse, mutect2
- CDKL5 | c.1915G>A p.A639T | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.996); catalogued as COSV66112434, COSV66112854; called by muse, mutect2, varscan2
- CELSR3 | c.9313A>G p.M3105V | Missense Mutation (SNP) | VAF 81/407 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs760663792; called by muse, mutect2, varscan2
- CEP104 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 54/241 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.738); catalogued as rs750473230, COSV65519184; called by muse, mutect2, varscan2
- CEP192 | c.3314C>G p.S1105* | Nonsense Mutation (SNP) | VAF 5/49 reads (10%) | catalogued as COSV58060153; called by muse, mutect2
- CHADL | c.2104G>T p.A702S | Missense Mutation (SNP) | VAF 72/362 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.472); catalogued as COSV53432918; called by muse, mutect2, varscan2
- CHD1L | c.2452G>A p.A818T | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as rs782014875; called by muse, mutect2, varscan2
- CHD7 | c.2273G>T p.R758L | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as CM149446; called by muse, mutect2, varscan2
- CHIC1 | c.281C>A p.A94D | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV100998275; called by muse, mutect2, varscan2
- CHRNA2 | c.778G>A p.V260I | Missense Mutation (SNP) | VAF 72/509 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as COSV53559296; called by muse, mutect2, varscan2
- CHST1 | c.1051C>T p.R351* | Nonsense Mutation (SNP) | VAF 44/220 reads (20%) | catalogued as rs748586532, COSV57322825; called by muse, mutect2, varscan2
- CILP2 | c.3154del p.L1052* | Frame Shift Del (DEL) | VAF 24/171 reads (14%) | catalogued as rs1434436891; called by mutect2, pindel, varscan2
- CLEC2L | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 54/270 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.258); catalogued as rs766831853, COSV70691481; called by muse, mutect2, varscan2
- CLEC4C | c.235+2T>C p.X79_splice | Splice Site (SNP) | VAF 17/66 reads (26%) | catalogued as COSV100665365; called by muse, mutect2, varscan2
- CLU | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 82/472 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.047); catalogued as COSV57066739; called by muse, mutect2, varscan2
- CLU | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 56/478 reads (12%) | SIFT tolerated (0.97); PolyPhen benign (0.07); catalogued as rs760456252; called by muse, mutect2, varscan2
- CNNM3 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 62/348 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as rs1180242273; called by muse, mutect2, varscan2
- COL1A2 | c.3238C>G p.R1080G | Missense Mutation (SNP) | VAF 68/429 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51961449; called by muse, mutect2, varscan2
- COL22A1 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs777346782, COSV57323338; called by muse, mutect2, varscan2
- COL25A1 | c.226C>T p.H76Y | Missense Mutation (SNP) | VAF 42/279 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV101211732; called by muse, varscan2
- COL4A4 | c.4151C>T p.A1384V | Missense Mutation (SNP) | VAF 41/254 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199911379; called by muse, mutect2, varscan2
- COL9A2 | c.104del p.P35Rfs*51 | Frame Shift Del (DEL) | VAF 30/221 reads (14%) | catalogued as rs761125486; called by mutect2, pindel, varscan2
- CORIN | c.2795G>A p.G932D | Missense Mutation (SNP) | VAF 38/213 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1165711315; called by muse, mutect2
- CP | c.469T>C p.Y157H | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1428076937; called by muse, mutect2, varscan2
- CPD | c.691del p.A231Pfs*32 | Frame Shift Del (DEL) | VAF 31/167 reads (19%) | catalogued as COSV56711742; called by mutect2, pindel, varscan2
- CPLANE2 | c.376G>C p.D126H | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as COSV65056888; called by muse, mutect2, varscan2
- CPN1 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 78/538 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770920497, COSV64941923; called by muse, mutect2, varscan2
- CPZ | c.403G>A p.A135T (on ENST00000360986 / NM_001014447.3; = p.A124T on NM_003652.3) | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs775620343, COSV59922528; called by muse, mutect2, varscan2
- CRACD | c.1964del p.R655Pfs*22 | Frame Shift Del (DEL) | VAF 54/328 reads (16%) | catalogued as COSV51715473; called by mutect2, pindel, varscan2
- CTHRC1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 25/249 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.732); catalogued as rs750559913, COSV104397952; called by muse, mutect2, varscan2
- CTNND2 | c.843G>T p.Q281H | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.34); catalogued as rs1351655239; called by muse, mutect2, varscan2
- CXCR4 | c.866C>G p.A289G | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as rs1021350572; called by muse, mutect2, varscan2
- DACT2 | c.1890del p.R633Gfs*124 | Frame Shift Del (DEL) | VAF 27/181 reads (15%) | catalogued as COSV64693789; called by mutect2, pindel, varscan2
- DAGLB | c.1894G>T p.G632C | Missense Mutation (SNP) | VAF 35/246 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as COSV51701952; called by muse, mutect2, varscan2
- DCDC1 | c.3414del p.L1140Sfs*36 (on ENST00000597505 / NM_001367979.1; = p.L247Sfs*36 on NM_020869.3) | Frame Shift Del (DEL) | VAF 11/75 reads (15%) | catalogued as COSV60307531, COSV60312679; called by mutect2, pindel, varscan2
- DCHS1 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 46/316 reads (15%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); catalogued as rs918577745; called by muse, mutect2, varscan2
- DCUN1D4 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755838496, COSV58122689; called by muse, mutect2, varscan2
- DEPDC1B | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 38/226 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780638515; called by muse, mutect2, varscan2
- DHRS11 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 28/488 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs1413138156; called by muse, mutect2
- DHX16 | c.1699G>A p.A567T | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs780140127, COSV64564893; called by muse, mutect2, varscan2
- DIP2A | c.2092C>A p.L698I | Missense Mutation (SNP) | VAF 44/279 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100596387; called by muse, varscan2
- DLC1 | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs148727515, COSV52324792; called by muse, mutect2, varscan2
- DLGAP2 | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 41/286 reads (14%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); catalogued as COSV70104335; called by muse, mutect2, varscan2
- DNAH5 | c.10796G>A p.R3599H | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754209888, COSV54207393, COSV54249998; called by muse, mutect2, varscan2
- DNAH8 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs367709378; called by muse, mutect2, varscan2
- DNASE2B | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.755); catalogued as rs762509494; called by muse, mutect2, varscan2
- DSCAM | c.4381C>T p.R1461C | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68027698; called by muse, mutect2, varscan2
- DUOX2 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 51/329 reads (16%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs1397188299; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1060del p.W354Gfs*2 | Frame Shift Del (DEL) | VAF 13/71 reads (18%) | catalogued as rs746928635; called by mutect2, pindel
- EDN2 | c.112C>T p.H38Y | Missense Mutation (SNP) | VAF 59/335 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs1039710418, COSV65423424; called by muse, mutect2, varscan2
- EHMT1 | c.1870G>T p.A624S | Missense Mutation (SNP) | VAF 110/354 reads (31%) | SIFT tolerated (0.67); PolyPhen benign (0.012); catalogued as rs146905719, COSV99055696; called by mutect2, varscan2
- EIF4G1 | c.1305del p.T436Pfs*86 (on ENST00000346169 / NM_198241.3; = p.T240Pfs*86 on NM_004953.5) | Frame Shift Del (DEL) | VAF 18/147 reads (12%) | catalogued as COSV104407217; called by mutect2, pindel, varscan2
- EMC1 | c.1979G>A p.R660Q | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs750358879, COSV100916448; called by muse, mutect2, varscan2
- ENDOU | c.911G>A p.R304H (on ENST00000422538 / NM_001172439.2; = p.R263H on NM_006025.4) | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.496); catalogued as rs376360794; called by muse, mutect2, varscan2
- EPN2 | c.1408del p.T470Qfs*5 | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | catalogued as rs756461692; called by mutect2, varscan2
- EPX | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 66/341 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761941430, COSV56599653; called by muse, mutect2, varscan2
- ERC2 | c.2359C>T p.R787C | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs371754235; called by muse, mutect2, varscan2
- ESF1 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 30/245 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1277847783, COSV52520081; called by muse, varscan2
- FAM135B | c.3695G>T p.R1232L | Missense Mutation (SNP) | VAF 32/400 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99419787; called by muse, mutect2
- FAM135B | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs766848974; called by muse, mutect2, varscan2
- FAM155B | c.554del p.N185Tfs*40 | Frame Shift Del (DEL) | VAF 42/134 reads (31%) | catalogued as rs749254240; called by mutect2, varscan2
- FAM189A2 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs748266947; called by muse, mutect2, varscan2
- FAM83H | c.1258G>A p.V420M | Missense Mutation (SNP) | VAF 102/611 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as rs1207913733; called by muse, mutect2, varscan2
- FAM83H | c.393del p.D132Tfs*12 | Frame Shift Del (DEL) | VAF 23/120 reads (19%) | catalogued as rs782484545, COSV101186939, COSV101187094; called by mutect2, pindel
- FAT3 | c.2260G>A p.D754N | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1408408990, COSV53116526; called by muse, mutect2, varscan2
- FBLN2 | c.2383C>T p.R795C | Missense Mutation (SNP) | VAF 35/238 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs764879617; called by muse, mutect2, varscan2
- FBXL7 | c.976A>G p.I326V | Missense Mutation (SNP) | VAF 40/249 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1309327652; called by muse, mutect2, varscan2
- FIG4 | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 44/313 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV57787402; called by muse, mutect2, varscan2
- FLG | c.3058T>G p.S1020A | Missense Mutation (SNP) | VAF 93/465 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs751476639, COSV64252444; called by muse, mutect2, varscan2
- FLNC | c.3475C>T p.R1159W | Missense Mutation (SNP) | VAF 64/355 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as rs760500171, COSV57951799; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FMO4 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147680748; called by muse, mutect2, varscan2
- FOXC1 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 108/605 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.381); catalogued as COSV66516676; called by muse, mutect2, varscan2
- FOXJ1 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs759471615; called by muse, mutect2, varscan2
- FSTL4 | c.2369dup p.T791Yfs*36 | Frame Shift Ins (INS) | VAF 12/108 reads (11%) | catalogued as rs765771244; called by mutect2, varscan2
- GABRA1 | c.1317G>T p.W439C | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.286); catalogued as COSV50115373; called by muse, mutect2, varscan2
- GABRA4 | c.335G>A p.G112D | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1377742204; called by muse, mutect2, varscan2
- GALNT7 | c.1460C>T p.S487L | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs775194329; called by muse, mutect2, varscan2
- GANAB | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 30/209 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748490428; called by muse, mutect2, varscan2
- GAS6 | c.53T>A p.L18Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1205210398; called by muse, varscan2
- GEMIN4 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.814); catalogued as COSV59793738; called by muse, mutect2, varscan2
- GGA2 | c.619C>A p.L207I | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767897040; called by muse, mutect2, varscan2
- GLRA4 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 80/236 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as rs754281260; called by muse, mutect2, varscan2
- GNAS | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 23/492 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.084); catalogued as rs1270188558, COSV58336274; called by muse, mutect2
- GNAS | c.1238C>G p.S413C | Missense Mutation (SNP) | VAF 100/606 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.201); catalogued as COSV58344038; called by muse, mutect2, varscan2
- GOLGB1 | c.2838del p.E947Sfs*20 | Frame Shift Del (DEL) | VAF 7/50 reads (14%) | catalogued as rs774978171; called by mutect2, pindel, varscan2
- GPR182 | c.274A>G p.I92V | Missense Mutation (SNP) | VAF 53/335 reads (16%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as rs1272241358; called by muse, mutect2, varscan2
- GPR32 | c.1063del p.R355Gfs*16 | Frame Shift Del (DEL) | VAF 17/42 reads (40%) | catalogued as rs751525642; called by mutect2, varscan2
- GPT | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs777851951; called by muse, mutect2, varscan2
- GREB1 | c.2879C>T p.A960V | Missense Mutation (SNP) | VAF 108/616 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1161072300, COSV52189304; called by muse, mutect2, varscan2
- GRHL1 | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61408717, COSV61408963; called by muse, mutect2, varscan2
- GRIN2C | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.333); catalogued as rs770563794; called by muse, mutect2, varscan2
- GRM3 | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 59/409 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs377667772; called by muse, mutect2, varscan2
- GSC | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 53/368 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99450159; called by muse, mutect2, varscan2
- GSX1 | c.268T>C p.Y90H | Missense Mutation (SNP) | VAF 11/296 reads (4%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.446); catalogued as rs1333655280; called by muse, mutect2
- GTF3C1 | c.6214C>T p.P2072S | Missense Mutation (SNP) | VAF 54/339 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs757673924, COSV100649405; called by muse, mutect2, varscan2
- GZMB | c.475A>G p.T159A | Missense Mutation (SNP) | VAF 14/427 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as COSV53542250; called by muse, mutect2
- H1-4 | c.227A>G p.N76S | Missense Mutation (SNP) | VAF 52/299 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs771489271, COSV56801333; called by muse, mutect2, varscan2
- H1-6 | c.499G>T p.G167W | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs147889373, COSV58090187; called by muse, mutect2, varscan2
- H1-6 | c.65C>A p.T22N | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as rs750898482; called by muse, mutect2, varscan2
- H2AC1 | c.229del p.T77Lfs*10 | Frame Shift Del (DEL) | VAF 13/99 reads (13%) | catalogued as rs778804735, COSV99032261; called by mutect2, pindel, varscan2
- HAGH | c.638del p.P213Rfs*61 | Frame Shift Del (DEL) | VAF 40/241 reads (17%) | catalogued as rs751524326; called by mutect2, pindel, varscan2
- HAND2 | c.247del p.V83Cfs*16 | Frame Shift Del (DEL) | VAF 16/104 reads (15%) | catalogued as CM105646; called by mutect2, varscan2
- HDGF | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as rs756060981; called by muse, mutect2, varscan2
- HLA-B | c.896-1G>T p.X299_splice | Splice Site (SNP) | VAF 10/52 reads (19%) | catalogued as COSV69520575, COSV69520821; called by muse, mutect2, varscan2
- HLTF | c.1472T>C p.I491T | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as rs998792177; called by muse, mutect2, varscan2
- HLX | c.1453C>T p.L485F | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.094); catalogued as rs757359206; called by muse, mutect2, varscan2
- HOOK2 | c.1568C>T p.A523V | Missense Mutation (SNP) | VAF 54/263 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.693); catalogued as COSV53404226; called by muse, mutect2, varscan2
- HOXD10 | c.968_970del p.K323del | In Frame Del (DEL) | VAF 26/200 reads (13%) | catalogued as rs1249052328; called by pindel, varscan2
- HPSE2 | c.1678C>T p.P560S | Missense Mutation (SNP) | VAF 46/291 reads (16%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.994); catalogued as COSV65202922; called by muse, mutect2, varscan2
- HSPBP1 | c.1067G>A p.S356N | Missense Mutation (SNP) | VAF 70/191 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV55334129; called by muse, mutect2, varscan2
- HTR1F | c.930del p.F310Lfs*2 | Frame Shift Del (DEL) | VAF 6/41 reads (15%) | catalogued as rs748579647; called by mutect2, pindel, varscan2
- HTR2A | c.1365G>T p.E455D | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV66327063; called by muse, mutect2
- HTR6 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 66/350 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as rs1383305702; called by muse, mutect2, varscan2
- ICA1 | c.611del p.N204Tfs*5 | Frame Shift Del (DEL) | VAF 16/98 reads (16%) | catalogued as rs747841314; called by mutect2, varscan2
- IFRD1 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 35/248 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.855); catalogued as rs1394616214; called by muse, varscan2
- IGF2 | c.686del p.P229Qfs*27 (on ENST00000434045 / NM_001127598.3; = p.P173Qfs*27 on NM_000612.6) | Frame Shift Del (DEL) | VAF 19/90 reads (21%) | catalogued as rs755455183; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- IGF2R | c.4750G>A p.V1584M | Missense Mutation (SNP) | VAF 49/304 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs140858283, COSV63627231; called by muse, mutect2, varscan2
- IGKV6D-21 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs376502520; called by muse, mutect2, varscan2
- IGSF9B | c.2617C>T p.R873C | Missense Mutation (SNP) | VAF 38/222 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs370337864; called by muse, varscan2
- IKZF3 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768846820, COSV53103039; called by muse, mutect2, varscan2
- INPP5K | c.874C>T p.H292Y | Missense Mutation (SNP) | VAF 37/236 reads (16%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs369543706; called by muse, mutect2, varscan2
- INSRR | c.2757del p.L920Cfs*37 | Frame Shift Del (DEL) | VAF 32/192 reads (17%) | catalogued as rs772259106; called by mutect2, pindel, varscan2
- INTS1 | c.4525G>A p.A1509T | Missense Mutation (SNP) | VAF 57/378 reads (15%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.001); catalogued as rs529706393; called by muse, mutect2, varscan2
- IRAG1 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 80/400 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); catalogued as rs765612867, COSV70212932; called by muse, mutect2, varscan2
- IRX4 | c.1337C>A p.P446H | Missense Mutation (SNP) | VAF 56/348 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs369407092, COSV51471746; called by muse, mutect2, varscan2
- IRX5 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 64/470 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM124324, COSV58058993; called by muse, mutect2, varscan2
- ITGA2B | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 66/408 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752213788, COSV52234793; called by muse, mutect2, varscan2
- ITGAD | c.3085G>A p.V1029I | Missense Mutation (SNP) | VAF 33/255 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754365583; called by muse, mutect2, varscan2
- ITGB4 | c.4598G>A p.R1533H | Missense Mutation (SNP) | VAF 91/540 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751357499; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITPRIP | c.1279G>A p.G427R | Missense Mutation (SNP) | VAF 51/241 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs759433930; called by muse, mutect2, varscan2
- JAK2 | c.3338G>A p.R1113H | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1437629509, COSV67618953; called by muse, mutect2, varscan2
- JARID2 | c.3671C>T p.A1224V | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as rs769367991, COSV100160321; called by muse, mutect2, varscan2
- KANSL3 | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs760552557; called by muse, mutect2, varscan2
- KAT5 | c.379G>A p.G127S | Missense Mutation (SNP) | VAF 55/337 reads (16%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.862); catalogued as rs777887005, COSV57729813; called by muse, mutect2, varscan2
- KCNA1 | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV66836912; called by muse, mutect2, varscan2
- KCNA6 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as COSV54974371; called by muse, mutect2, varscan2
- KCNB2 | c.1949del p.P650Rfs*3 | Frame Shift Del (DEL) | VAF 30/241 reads (12%) | catalogued as COSV101578823; called by mutect2, pindel, varscan2
- KCNH1 | c.2573C>T p.S858L (on ENST00000271751 / NM_172362.3; = p.S831L on NM_002238.4) | Missense Mutation (SNP) | VAF 63/473 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); catalogued as rs754509705, COSV55074872; called by muse, mutect2, varscan2
- KCNU1 | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as rs368642765; called by muse, mutect2, varscan2
- KDM3A | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs760893813; called by muse, mutect2, varscan2
- KDM5A | c.1405C>A p.P469T | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66991956; called by muse, mutect2, varscan2
- KIF1C | c.1241C>T p.S414L | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs745355114; called by muse, mutect2, varscan2
- KIF23 | c.2857G>A p.A953T (on ENST00000260363; = p.A849T on NM_004856.7) | Missense Mutation (SNP) | VAF 44/290 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.355); catalogued as rs1281499873, COSV52980071, COSV99532701; called by muse, mutect2, varscan2
- KIF26B | c.5157dup p.S1720Qfs*269 | Frame Shift Ins (INS) | VAF 66/409 reads (16%) | catalogued as rs1385639497; called by mutect2, pindel, varscan2
- KLHDC7A | c.1325C>T p.A442V | Missense Mutation (SNP) | VAF 47/311 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769443248; called by muse, mutect2, varscan2
- KLHDC7A | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 56/334 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs754844164; called by muse, mutect2, varscan2
- KLHL35 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 43/266 reads (16%) | SIFT tolerated, low confidence (0.07); catalogued as COSV100409107; called by muse, mutect2, varscan2
- KLKB1 | c.953G>A p.C318Y | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1426696009; called by muse, mutect2, varscan2
- KMT2D | c.13948del p.E4650Sfs*16 | Frame Shift Del (DEL) | VAF 36/263 reads (14%) | catalogued as COSV56467227; called by mutect2, pindel, varscan2
- KRT81 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 84/680 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.146); catalogued as rs201504587; called by muse, mutect2
- KRT83 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 119/599 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs1194656235, COSV53340254; called by muse, mutect2, varscan2
- KRT85 | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 87/552 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.26); catalogued as rs757891287, COSV57737641; called by muse, mutect2, varscan2
- KRTAP10-11 | c.353T>A p.V118D | Missense Mutation (SNP) | VAF 105/616 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.151); catalogued as rs782500561; called by muse, mutect2, varscan2
- KRTAP4-9 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 16/332 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); catalogued as rs756953992; called by muse, mutect2
- LCP1 | c.1120T>C p.Y374H | Missense Mutation (SNP) | VAF 43/301 reads (14%) | SIFT tolerated (0.92); PolyPhen probably damaging (1); catalogued as rs763803335; called by muse, mutect2, varscan2
- LCT | c.4037G>A p.R1346H | Missense Mutation (SNP) | VAF 44/340 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51552593, COSV99929880; called by muse, mutect2, varscan2
- LIPF | c.223G>T p.G75C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV99490056; called by muse, mutect2
- LMO3 | c.232G>T p.A78S | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (1); PolyPhen possibly damaging (0.506); catalogued as rs1300711639, COSV53783937; called by muse, mutect2, varscan2
- LNPEP | c.434del p.N145Tfs*6 | Frame Shift Del (DEL) | VAF 40/194 reads (21%) | catalogued as rs748712732; called by mutect2, varscan2
- LOXHD1 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 41/242 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs369244277; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRFN1 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.197); catalogued as rs1425273957; called by muse, mutect2, varscan2
- LRP1B | c.5432C>A p.P1811H | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.628); catalogued as COSV101257023; called by muse, mutect2, varscan2
- LRRC45 | c.329_331del p.L110del | In Frame Del (DEL) | VAF 4/36 reads (11%) | catalogued as rs1396133461; called by pindel, varscan2
- LRRN4 | c.2107G>A p.A703T | Missense Mutation (SNP) | VAF 46/368 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs1348703152, COSV66645548; called by muse, mutect2, varscan2
- LRRTM3 | c.1463C>T p.T488M | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV100791880; called by muse, mutect2, varscan2
- LUZP2 | c.413del p.N138Tfs*24 | Frame Shift Del (DEL) | VAF 18/126 reads (14%) | catalogued as COSV61198175; called by pindel, varscan2
- MAML1 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.098); catalogued as COSV52983263; called by muse, mutect2, varscan2
- MAN1C1 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 46/278 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as COSV56045210; called by muse, mutect2, varscan2
- MAN2B2 | c.1959G>T p.E653D | Missense Mutation (SNP) | VAF 39/215 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.286); catalogued as rs1330888474; called by muse, mutect2, varscan2
- MAP3K1 | c.1439G>A p.R480K | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.952); catalogued as COSV68124336; called by muse, mutect2, varscan2
- MARCHF8 | c.316G>A p.V106M | Missense Mutation (SNP) | VAF 27/264 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs764974517, COSV100165721; called by muse, mutect2
- MARVELD2 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.293); catalogued as rs556047320, COSV100347648; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MB21D2 | c.647del p.N216Mfs*11 | Frame Shift Del (DEL) | VAF 42/250 reads (17%) | catalogued as rs748185381; called by mutect2, varscan2
- MBNL1 | c.979A>G p.M327V (on ENST00000282486 / NM_207293.2; = p.M309V on NM_021038.5 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as rs199584167; called by muse, mutect2, varscan2
- MCHR1 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 57/391 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.442); catalogued as rs199641758, COSV50762679; called by muse, mutect2, varscan2
- MDGA2 | c.1475del p.G492Efs*22 (on ENST00000399232 / NM_001113498.2; = p.G194Efs*22 on NM_182830.4) | Frame Shift Del (DEL) | VAF 14/76 reads (18%) | catalogued as COSV62096724; called by mutect2, pindel
- MDGA2 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV62105409; called by muse, mutect2, varscan2
- MDN1 | c.5966del p.K1989Rfs*65 | Frame Shift Del (DEL) | VAF 7/38 reads (18%) | catalogued as rs750092100; called by mutect2, varscan2
- MDN1 | c.3164C>T p.T1055M | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as rs745553494, COSV65525330; called by muse, mutect2, varscan2
- MEFV | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 34/267 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.033); catalogued as rs1399033974, COSV54821238; called by muse, mutect2, varscan2
- MESP2 | c.718del p.V240Sfs*241 | Frame Shift Del (DEL) | VAF 23/206 reads (11%) | catalogued as rs756232049; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- MFSD9 | c.1326del p.S443Afs*6 | Frame Shift Del (DEL) | VAF 21/114 reads (18%) | catalogued as rs769987847; called by mutect2, pindel, varscan2
- MIA2 | c.1270G>A p.A424T | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.059); catalogued as rs754080800; called by muse, mutect2, varscan2
- MICAL2 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs750975984, COSV99817884; called by muse, mutect2, varscan2
- MIF4GD | c.547C>T p.L183F (on ENST00000325102 / NM_001370592.1; = p.L217F on NM_020679.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 138/787 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1264119760; called by muse, mutect2, varscan2
- MMP21 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs762983237; called by muse, mutect2
- MORC3 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 40/263 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs773678802, COSV68689121; called by muse, mutect2, varscan2
- MPI | c.1022del p.P341Lfs*8 | Frame Shift Del (DEL) | VAF 54/387 reads (14%) | catalogued as rs765310894; called by mutect2, pindel, varscan2
- MROH2B | c.3493C>T p.L1165F | Missense Mutation (SNP) | VAF 30/247 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.564); catalogued as rs1385323187; called by muse, mutect2, varscan2
- MTRR | c.290G>A p.R97H (on ENST00000264668; = p.R70H on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/292 reads (16%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.867); catalogued as rs777202031, COSV52941860, COSV99241730; ClinVar: uncertain significance; called by mutect2, varscan2
- MUC16 | c.35924C>T p.A11975V | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); catalogued as rs751941792; called by muse, mutect2, varscan2
- MUC5B | c.12800C>G p.A4267G | Missense Mutation (SNP) | VAF 20/450 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.135); catalogued as COSV71590545; called by muse, mutect2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 46/228 reads (20%) | catalogued as rs764857791; called by mutect2, pindel, varscan2
- NACC2 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.84); catalogued as rs1377204014; called by muse, varscan2
- NAV3 | c.2951C>T p.S984L | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as rs1005877698, COSV57058762; called by muse, mutect2, varscan2
- NCAPD3 | c.2725del p.Q909Rfs*10 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | catalogued as rs770284236; called by mutect2, pindel, varscan2
- NDUFV1 | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 113/652 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs767193537, COSV59595743; called by muse, mutect2, varscan2
- NID1 | c.3299G>A p.R1100Q | Missense Mutation (SNP) | VAF 60/304 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs779614790; called by muse, mutect2, varscan2
- NKX1-2 | c.250del p.L84Wfs*31 | Frame Shift Del (DEL) | VAF 33/259 reads (13%) | catalogued as rs1554873967; called by mutect2, pindel, varscan2
- NKX2-6 | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 45/267 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.052); catalogued as COSV61493624; called by muse, mutect2, varscan2
- NME8 | c.881C>G p.A294G | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.028); catalogued as COSV99553849, COSV99553898; called by muse, mutect2, varscan2
- NOS3 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs41508746; called by muse, mutect2, varscan2
- NOTCH1 | c.4325del p.P1442Rfs*3 | Frame Shift Del (DEL) | VAF 46/153 reads (30%) | catalogued as COSV53045529; called by mutect2, pindel, varscan2
- NOTCH3 | c.3737T>C p.V1246A | Missense Mutation (SNP) | VAF 84/512 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs776076696; called by muse, mutect2, varscan2
- NPY | c.157C>T p.R53* | Nonsense Mutation (SNP) | VAF 35/228 reads (15%) | catalogued as COSV54215115; called by muse, mutect2, varscan2
- NREP | c.205del p.*69Nfs*59 | Frame Shift Del (DEL) | VAF 34/170 reads (20%) | catalogued as COSV57405086; called by mutect2, pindel, varscan2
- NRXN1 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 47/249 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.2); catalogued as rs796052775, COSV68014124; ClinVar: uncertain significance; called by muse, varscan2
- NTN1 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 60/342 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs772623927, COSV51478331; called by muse, mutect2, varscan2
- NYAP1 | c.1828G>A p.A610T | Missense Mutation (SNP) | VAF 33/253 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs778518564, COSV55720246; called by muse, mutect2, varscan2
- OBSCN | c.13187G>A p.R4396H | Missense Mutation (SNP) | VAF 54/355 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs371612842; called by muse, varscan2
- ODC1 | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 67/345 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.176); catalogued as COSV104374922; called by muse, mutect2, varscan2
- OR10C1 | c.49G>A p.G17S (on ENST00000622521; = p.G15S on NM_013941.3) | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.451); catalogued as rs762428895; called by muse, mutect2
- OR1E1 | c.304T>C p.Y102H | Missense Mutation (SNP) | VAF 59/388 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV59459687; called by muse, mutect2, varscan2
- OR2T12 | c.617T>A p.L206Q | Missense Mutation (SNP) | VAF 57/467 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100527879; called by muse, mutect2, varscan2
- OR4F6 | c.569T>C p.I190T | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs1280365931; called by muse, mutect2, varscan2
- OR51D1 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 40/222 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs144776786; called by muse, mutect2, varscan2
- OR51M1 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 44/322 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1455584006; called by muse, mutect2, varscan2
- OR52I2 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 87/515 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1280112761; called by muse, mutect2, varscan2
- OR5T2 | c.526T>C p.S176P | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as rs762249472; called by muse, mutect2
- OSBPL2 | c.355A>T p.R119W (on ENST00000313733 / NM_144498.4; = p.R107W on NM_014835.4) | Missense Mutation (SNP) | VAF 35/229 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV100569127; called by muse, mutect2, varscan2
- OTOG | c.1071del p.F358Lfs*28 | Frame Shift Del (DEL) | VAF 67/433 reads (15%) | catalogued as rs887476134; called by mutect2, pindel, varscan2
- OTULIN | c.983C>A p.P328Q | Missense Mutation (SNP) | VAF 29/255 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.184); catalogued as COSV52506908; called by muse, mutect2, varscan2
- OXTR | c.193C>A p.R65S | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.339); catalogued as COSV57478553; called by muse, mutect2
- PACSIN2 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 112/623 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs771412703; called by muse, mutect2, varscan2
- PAPPA2 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 38/246 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs764274557, COSV62776310; called by muse, mutect2, varscan2
- PARP12 | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 35/238 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs149334393, COSV54932877; called by muse, mutect2, varscan2
- PCDH10 | c.679dup p.Q227Pfs*19 | Frame Shift Ins (INS) | VAF 12/37 reads (32%) | catalogued as rs762465989; called by mutect2, varscan2
- PCDH10 | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 67/422 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.02); catalogued as COSV52093453, COSV52099771; called by muse, mutect2, varscan2
- PCDH15 | c.4049G>A p.R1350H | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs752356781, COSV57265804, COSV57366433; ClinVar: uncertain significance; called by muse, mutect2
- PCDH17 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 97/540 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100932164; called by muse, mutect2, varscan2
- PCDH9 | c.3145C>T p.R1049C (on ENST00000377865 / NM_203487.3; = p.R1015C on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs776798396, COSV60527884, COSV60555212; called by muse, mutect2, varscan2
- PCDHA13 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 123/694 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.017); catalogued as COSV99170121; called by muse, mutect2, varscan2
- PCDHA7 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 74/488 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1359916127; called by muse, mutect2, varscan2
- PCDHB10 | c.253C>T p.L85F | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.125); catalogued as rs782552272; called by muse, mutect2, varscan2
- PCDHB2 | c.2227G>T p.G743C | Missense Mutation (SNP) | VAF 52/359 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs1360034037; called by muse, mutect2, varscan2
- PCDHGA12 | c.988C>T p.R330* | Nonsense Mutation (SNP) | VAF 20/104 reads (19%) | catalogued as rs371020840; called by muse, mutect2, varscan2
- PCDHGA7 | c.287G>A p.C96Y | Missense Mutation (SNP) | VAF 50/301 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.896); catalogued as rs760844021; called by muse, mutect2, varscan2
- PCDHGA9 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 61/305 reads (20%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.053); catalogued as rs940508173, COSV53940340, COSV54011834; called by muse, mutect2, varscan2
- PCDHGB6 | c.2033G>A p.R678H | Missense Mutation (SNP) | VAF 34/256 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs753193390, COSV99550096; called by muse, mutect2, varscan2
- PCDHGC3 | c.2348C>T p.A783V | Missense Mutation (SNP) | VAF 50/255 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.025); catalogued as rs1405449066; called by muse, mutect2, varscan2
- PCLO | c.3335A>G p.Q1112R | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV100433535; called by mutect2, varscan2
- PCNX4 | c.3395A>G p.D1132G (on ENST00000406854 / NM_001330177.2; = p.D898G on NM_022495.5) | Missense Mutation (SNP) | VAF 35/233 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58307567; called by muse, mutect2, varscan2
- PDE4DIP | c.2485C>T p.R829C | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.286); catalogued as rs781928446, COSV57684904; called by muse, mutect2
- PEAR1 | c.755dup p.G253Wfs*33 | Frame Shift Ins (INS) | VAF 7/48 reads (15%) | catalogued as rs761323492; called by mutect2, pindel, varscan2
- PHTF1 | c.1605del p.F535Lfs*13 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | catalogued as rs1441071372; called by mutect2, pindel, varscan2
- PIK3C2A | c.340del p.T114Hfs*10 | Frame Shift Del (DEL) | VAF 22/110 reads (20%) | catalogued as COSV56402935; called by mutect2, varscan2
- PKD1L1 | c.6761G>A p.R2254H | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as rs750076751, COSV56967493; called by muse, mutect2, varscan2
- PKDREJ | c.5909C>T p.A1970V | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs778949556; called by muse, mutect2, varscan2
- PKN1 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 31/234 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as rs770772273, COSV54397221, COSV54403488; called by muse, mutect2, varscan2
- PKN1 | c.596del p.P199Rfs*59 | Frame Shift Del (DEL) | VAF 28/199 reads (14%) | catalogued as COSV54402051; called by mutect2, pindel, varscan2
- PLA2G4F | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 55/343 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.332); catalogued as rs1244542153; called by muse, mutect2, varscan2
- PLBD2 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as rs796098352; called by muse, mutect2, varscan2
- PLCG2 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1353659689, COSV63867883; called by muse, mutect2, varscan2
- PLCXD3 | c.625G>T p.G209W | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760798700, COSV60607879, COSV60614780; called by muse, mutect2, varscan2
- PLSCR5 | c.275del p.N92Tfs*30 | Frame Shift Del (DEL) | VAF 25/129 reads (19%) | catalogued as COSV71649027; called by mutect2, pindel, varscan2
- PMEPA1 | c.624del p.S209Afs*61 | Frame Shift Del (DEL) | VAF 25/190 reads (13%) | catalogued as rs751873496; called by mutect2, pindel, varscan2
- POLD3 | c.898del p.R300Gfs*5 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs761423306, COSV55240660; called by mutect2, varscan2
- POLN | c.212del p.K71Rfs*6 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | catalogued as rs760971697; called by pindel, varscan2
- POLR1A | c.4916G>A p.R1639H | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747827280, COSV55692443; called by muse, mutect2, varscan2
- POTEA | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as rs767546235; called by muse, mutect2, varscan2
- PPP2CB | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 32/250 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs1452677282; called by muse, mutect2, varscan2
- PPP4R3A | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 28/204 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs768951187, COSV61504472; called by muse, mutect2, varscan2
- PPP6R2 | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs140951188; called by muse, mutect2, varscan2
- PRAG1 | c.1627G>A p.A543T | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs377570909, COSV58163685; called by muse, mutect2, varscan2
- PRAM1 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as COSV99725832; called by muse, varscan2
- PRAME | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.139); catalogued as rs771542086; called by muse, mutect2, varscan2
- PRAMEF8 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 84/808 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as rs1218205281; called by muse, mutect2, varscan2
- PRKAG2 | c.1159G>A p.V387I | Missense Mutation (SNP) | VAF 38/242 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.209); catalogued as rs778811623, COSV104382967, COSV55230001; called by muse, mutect2, varscan2
- PRKAR1B | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 44/217 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.329); catalogued as COSV64318475; called by muse, mutect2, varscan2
- PRPF39 | c.13C>T p.H5Y | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.092); catalogued as rs1241823824; called by mutect2, varscan2
- PRPF4B | c.2004G>T p.W668C | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61783535; called by muse, mutect2
- PRR22 | c.309del p.P104Qfs*73 | Frame Shift Del (DEL) | VAF 46/204 reads (23%) | catalogued as rs750173586; called by mutect2, pindel, varscan2
- PSD4 | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 27/261 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV55525505; called by muse, mutect2, varscan2
- PTCH1 | c.1667T>C p.V556A | Missense Mutation (SNP) | VAF 124/692 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.137); catalogued as COSV59496338; called by muse, mutect2, varscan2
- PTCH2 | c.3505del p.L1169Cfs*85 | Frame Shift Del (DEL) | VAF 18/107 reads (17%) | catalogued as rs763413121; called by mutect2, varscan2
- PTCHD3 | c.1764del p.F588Lfs*18 | Frame Shift Del (DEL) | VAF 12/78 reads (15%) | catalogued as rs1448522271; called by mutect2, pindel, varscan2
- PTGDR | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.844); catalogued as rs1424250237; called by muse, mutect2, varscan2
- PWWP2A | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 44/281 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.249); catalogued as rs761398943; called by muse, mutect2, varscan2
- PYROXD1 | c.1458_1460del p.E486del | In Frame Del (DEL) | VAF 18/73 reads (25%) | catalogued as rs759115867; called by pindel, varscan2
- RAB30 | c.574A>G p.K192E | Missense Mutation (SNP) | VAF 43/193 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as COSV99475958; called by muse, mutect2, varscan2
- RAMP3 | c.344del p.P115Qfs*8 | Frame Shift Del (DEL) | VAF 83/533 reads (16%) | catalogued as rs763340102; called by mutect2, pindel, varscan2
- RASAL2 | c.379C>T p.R127* | Nonsense Mutation (SNP) | VAF 19/127 reads (15%) | catalogued as rs1433236647; called by muse, mutect2, varscan2
- RBL1 | c.1876C>T p.R626* | Nonsense Mutation (SNP) | VAF 38/214 reads (18%) | catalogued as rs778997257, COSV60328604; called by muse, mutect2, varscan2
- RBL1 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs964394221; called by muse, mutect2
- RBM41 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.538); catalogued as rs769714202, COSV99179841; called by muse, mutect2, varscan2
- REM1 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 69/408 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52427424; called by muse, mutect2, varscan2
- RESF1 | c.2662G>C p.D888H | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV100440449, COSV57020000; called by muse, mutect2, varscan2
- RGS22 | c.3019C>T p.P1007S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.073); catalogued as rs769248020, COSV62662139; called by muse, mutect2, varscan2
- RIBC2 | c.109G>C p.A37P | Missense Mutation (SNP) | VAF 33/207 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as rs532668203; called by muse, mutect2, varscan2
- RLN2 | c.20del p.F7Sfs*4 | Frame Shift Del (DEL) | VAF 28/130 reads (22%) | catalogued as rs760343057; called by mutect2, varscan2
- RNF126 | c.547del p.A183Pfs*41 | Frame Shift Del (DEL) | VAF 32/176 reads (18%) | catalogued as COSV52777670; called by mutect2, pindel, varscan2
- ROS1 | c.3863A>G p.Y1288C | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1481438598; called by muse, varscan2
- RPAIN | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375001488; called by muse, varscan2
- RPN2 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 43/248 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.625); catalogued as rs765214512; called by muse, mutect2, varscan2
- RPS6KC1 | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761043603, COSV65300363; called by muse, mutect2, varscan2
- RUNX1T1 | c.607G>A p.A203T (on ENST00000265814 / NM_001198628.1; = p.A176T on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/301 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV56158632; called by muse, mutect2, varscan2
- RYR3 | c.7784G>A p.G2595D (on ENST00000389232; = p.G2596D on NM_001036.6) | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV66787096; called by muse, mutect2, varscan2
- SBF2 | c.424A>G p.T142A | Missense Mutation (SNP) | VAF 31/265 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as rs1473313008; called by muse, mutect2, varscan2
- SCFD1 | c.1723C>T p.R575W | Missense Mutation (SNP) | VAF 36/211 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs753170714, COSV61722253; called by muse, mutect2, varscan2
- SCN4A | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 40/241 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); catalogued as COSV71126633; called by muse, mutect2, varscan2
- SEC14L5 | c.1033G>A p.V345M | Missense Mutation (SNP) | VAF 41/219 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs1410275416; called by muse, mutect2, varscan2
- SEC31B | c.1267C>G p.Q423E | Missense Mutation (SNP) | VAF 33/210 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764289728; called by muse, mutect2, varscan2
- SEMA6C | c.1781del p.P594Qfs*157 | Frame Shift Del (DEL) | VAF 13/111 reads (12%) | catalogued as rs758949234, COSV59006634; called by mutect2, pindel
- SERPINA6 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 55/350 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.071); catalogued as rs202078426, COSV58583804; called by muse, mutect2, varscan2
- SERPINF1 | c.77del p.P26Rfs*26 | Frame Shift Del (DEL) | VAF 36/225 reads (16%) | catalogued as rs1272920425; called by mutect2, pindel, varscan2
- SETD1B | c.5543C>T p.A1848V | Missense Mutation (SNP) | VAF 77/493 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs780663276; called by muse, mutect2, varscan2
- SETD2 | c.3244G>A p.E1082K | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.664); catalogued as rs764499297; called by muse, mutect2, varscan2
- SETDB1 | c.3593G>A p.R1198H | Missense Mutation (SNP) | VAF 57/325 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54987178; called by muse, mutect2, varscan2
- SFI1 | c.2527C>T p.R843W (on ENST00000400288 / NM_001007467.3; = p.R812W on NM_014775.4) | Missense Mutation (SNP) | VAF 64/366 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs367957589; called by muse, mutect2, varscan2
- SH3GL1 | c.584_586del p.E195del | In Frame Del (DEL) | VAF 76/387 reads (20%) | catalogued as rs1410827972; called by pindel, varscan2
- SH3RF1 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs747035534, COSV52917869; called by muse, mutect2
- SHB | c.124del p.Q42Rfs*199 | Frame Shift Del (DEL) | VAF 29/149 reads (19%) | catalogued as rs778597364; called by mutect2, varscan2
- SHC1 | c.92del p.P31Rfs*35 | Frame Shift Del (DEL) | VAF 13/117 reads (11%) | catalogued as rs752843778; called by mutect2, pindel, varscan2
- SHISA7 | c.1380del p.P462Qfs*75 | Frame Shift Del (DEL) | VAF 11/74 reads (15%) | catalogued as rs1275449767; called by mutect2, varscan2
- SHLD2 | c.202A>G p.I68V | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1210871678; called by muse, mutect2, varscan2
- SIAE | c.733T>G p.Y245D | Missense Mutation (SNP) | VAF 41/189 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV55015699; called by muse, mutect2, varscan2
- SIAE | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 55/383 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV55013345; called by muse, mutect2, varscan2
- SIRPA | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 53/302 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.653); catalogued as rs754503197, COSV61541071; called by muse, mutect2, varscan2
- SIRPA | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 37/248 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as rs748023319, COSV61540208; called by muse, mutect2, varscan2
- SKOR1 | c.913G>A p.G305S | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.86); catalogued as rs759761817; called by muse, mutect2, varscan2
- SLC16A11 | c.850G>A p.A284T (on ENST00000308009; = p.A260T on NM_153357.3) | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs1257915610; called by muse, mutect2, varscan2
- SLC17A8 | c.307A>G p.M103V | Missense Mutation (SNP) | VAF 54/309 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs537974883; called by muse, mutect2, varscan2
- SLC22A7 | c.919C>T p.R307W (on ENST00000372585 / NM_153320.2; = p.R305W on NM_006672.3) | Missense Mutation (SNP) | VAF 46/309 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.149); catalogued as rs572582792, COSV51485837; called by muse, mutect2, varscan2
- SLC38A8 | c.251G>A p.G84D | Missense Mutation (SNP) | VAF 110/596 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.909); catalogued as rs1400885668; called by muse, mutect2, varscan2
- SLC39A5 | c.1207G>T p.G403C | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201919253; called by muse, mutect2, varscan2
- SLC43A1 | c.310del p.R104Dfs*31 | Frame Shift Del (DEL) | VAF 45/251 reads (18%) | catalogued as COSV99561247; called by mutect2, pindel, varscan2
- SLC44A4 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1351382001; called by muse, mutect2, varscan2
- SLC45A4 | c.2398del p.I800Ffs*53 (on ENST00000517878 / NM_001286646.2; = p.K746Nfs*13 on NM_001080431.2) | Frame Shift Del (DEL) | VAF 16/119 reads (13%) | catalogued as rs765323954, COSV99198528; called by mutect2, varscan2
- SLC6A17 | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs781385140; called by muse, mutect2, varscan2
- SLCO3A1 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 73/530 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as COSV59230802; called by muse, mutect2, varscan2
- SLIT1 | c.3773T>C p.V1258A | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); catalogued as rs1415603189; called by muse, mutect2
- SMAD4 | c.817A>T p.T273S | Missense Mutation (SNP) | VAF 12/361 reads (3%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV61696456; called by muse, mutect2
- SMARCA4 | c.3986G>A p.R1329H | Missense Mutation (SNP) | VAF 74/400 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs1555785361, COSV60805043; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNTG1 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 37/316 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs200299603; called by muse, mutect2, varscan2
- SNX25 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs779242791; called by muse, mutect2, varscan2
- SORBS2 | c.2023G>A p.E675K | Missense Mutation (SNP) | VAF 52/425 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52996293; called by muse, mutect2, varscan2
- SORL1 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.023); catalogued as rs369018073; called by muse, mutect2, varscan2
- SORL1 | c.4967A>G p.N1656S | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1258904021; called by muse, mutect2, varscan2
- SOX15 | c.498del p.S167Afs*64 | Frame Shift Del (DEL) | VAF 18/104 reads (17%) | catalogued as rs1214200459; called by mutect2, pindel, varscan2
- SOX5 | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 29/241 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as rs762621219, COSV58650862; called by muse, mutect2, varscan2
- SOX7 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 41/240 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs775918915, COSV58730250; called by muse, mutect2, varscan2
- SPATA20 | c.1679G>T p.G560V (on ENST00000356488 / NM_001258372.1; = p.G576V on NM_022827.4) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs550739517; called by muse, mutect2, varscan2
- SPEG | c.9734A>G p.Q3245R | Missense Mutation (SNP) | VAF 57/377 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV100405095; called by muse, mutect2, varscan2
- SPG21 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 45/223 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as rs750152389; called by muse, mutect2, varscan2
- SPIRE1 | c.1700G>A p.R567H (on ENST00000409402 / NM_001128626.2; = p.R553H on NM_020148.3) | Missense Mutation (SNP) | VAF 23/198 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs534205788, COSV59162530; called by muse, mutect2, varscan2
- SRGAP2B | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as rs781893653, COSV101523407; called by muse, mutect2
- SSUH2 | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as rs753118608, COSV104397058; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.761T>C p.V254A | Missense Mutation (SNP) | VAF 20/124 reads (16%) | PolyPhen probably damaging (0.995); catalogued as COSV100602763; called by muse, mutect2, varscan2
- STARD9 | c.7195C>T p.R2399C | Missense Mutation (SNP) | VAF 36/229 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1227651761, COSV51902625; called by muse, mutect2, varscan2
- STIM1 | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 33/219 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs375914426; called by muse, mutect2, varscan2
- SUGCT | c.255del p.P86Hfs*31 | Frame Shift Del (DEL) | VAF 26/152 reads (17%) | catalogued as COSV99999838; called by pindel, varscan2
- SYBU | c.736C>T p.R246C (on ENST00000276646 / NM_001099754.2; = p.R245C on NM_017786.6) | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373047133; called by mutect2, varscan2
- SYNJ2 | c.608C>A p.A203D | Missense Mutation (SNP) | VAF 52/303 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1030044089; called by muse, varscan2
- SYNPO | c.2435G>A p.R812H (on ENST00000394243 / NM_001166208.2; = p.R568H on NM_007286.6) | Missense Mutation (SNP) | VAF 131/754 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as rs1264912311; called by muse, mutect2, varscan2
- TAP2 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 111/538 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs750440758, COSV66498960; called by muse, mutect2, varscan2
- TARS1 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 33/222 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs144362717; called by muse, mutect2, varscan2
- TAS2R4 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs1196811856; called by muse, varscan2
- TAS2R4 | c.419C>G p.S140C | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1286949996; called by muse, varscan2
- TBC1D22B | c.530del p.P177Qfs*2 | Frame Shift Del (DEL) | VAF 12/109 reads (11%) | catalogued as rs757209781; called by mutect2, pindel, varscan2
- TBX22 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 50/171 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1407601790, COSV64784842; called by muse, mutect2, varscan2
- TBX3 | c.1129G>A p.A377T (on ENST00000257566 / NM_016569.4; = p.A357T on NM_005996.4) | Missense Mutation (SNP) | VAF 75/477 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs780968472, COSV99983498; called by muse, mutect2, varscan2
- TBX4 | c.1112del p.P371Lfs*8 | Frame Shift Del (DEL) | VAF 14/82 reads (17%) | catalogued as rs754897911; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- TBXAS1 | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 68/462 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs1302728912; called by muse, mutect2, varscan2
- TCAF1 | c.539G>A p.G180D | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1346072740; called by muse, mutect2
- TCF25 | c.1415G>A p.R472Q | Missense Mutation (SNP) | VAF 49/334 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs746554879; called by muse, mutect2, varscan2
- TEX36 | c.13C>T p.R5* | Nonsense Mutation (SNP) | VAF 33/231 reads (14%) | catalogued as rs757285455, COSV64314759; called by muse, mutect2, varscan2
- TH | c.396G>T p.K132N (on ENST00000381178 / NM_199292.3; = p.K101N on NM_000360.4) | Missense Mutation (SNP) | VAF 44/297 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as COSV100147054; called by muse, mutect2, varscan2
- THBS1 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.467); catalogued as rs370731208; called by muse, mutect2, varscan2
- THNSL2 | c.83del p.G28Afs*28 | Frame Shift Del (DEL) | VAF 10/67 reads (15%) | catalogued as COSV59082141; called by mutect2, pindel
- TINAGL1 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54699454; called by muse, mutect2, varscan2
- TLE4 | c.1475C>T p.A492V | Missense Mutation (SNP) | VAF 48/280 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54629718; called by muse, mutect2, varscan2
- TLNRD1 | c.358G>A p.V120M | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs753023700; called by muse, mutect2, varscan2
- TLR9 | c.1672C>T p.P558S | Missense Mutation (SNP) | VAF 63/290 reads (22%) | SIFT tolerated (0.97); PolyPhen benign (0.062); catalogued as rs756045938, COSV100645638; called by muse, mutect2, varscan2
- TMA16 | c.45del p.V16Sfs*25 | Frame Shift Del (DEL) | VAF 23/123 reads (19%) | catalogued as rs570113265, COSV62187391; called by mutect2, varscan2
- TMC4 | c.1001C>T p.A334V (on ENST00000617472 / NM_001145303.3; = p.A328V on NM_144686.4) | Missense Mutation (SNP) | VAF 40/246 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV55826439; called by muse, mutect2, varscan2
- TMEFF1 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1426305571, COSV100615082; called by muse, mutect2
- TMEM131L | c.3076C>T p.R1026C | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1440163720, COSV53648230; called by muse, mutect2, varscan2
- TMEM132C | c.2498G>A p.R833H | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.886); catalogued as rs750924400; called by muse, mutect2, varscan2
- TMEM163 | c.385G>A p.V129I | Missense Mutation (SNP) | VAF 45/263 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1375272110; called by muse, mutect2, varscan2
- TMEM200C | c.794del p.G265Afs*112 | Frame Shift Del (DEL) | VAF 34/222 reads (15%) | catalogued as rs1382646421; called by mutect2, pindel, varscan2
- TMPRSS2 | c.239-1G>T p.X80_splice | Splice Site (SNP) | VAF 31/148 reads (21%) | catalogued as COSV100152292; called by muse, mutect2, varscan2
- TMTC3 | c.1101del p.P368Qfs*22 | Frame Shift Del (DEL) | VAF 16/100 reads (16%) | catalogued as rs751346733; called by mutect2, varscan2
- TOP3B | c.1358C>T p.T453M | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV64116913; called by muse, mutect2, varscan2
- TOR2A | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 66/157 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as rs543471487; called by muse, mutect2, varscan2
- TOX | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 46/312 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1412196962, COSV63844041; called by muse, mutect2, varscan2
- TP53BP2 | c.2297C>T p.A766V (on ENST00000343537 / NM_001031685.3; = p.A637V on NM_005426.2) | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.278); catalogued as rs377715637; called by muse, mutect2, varscan2
- TPO | c.2789C>T p.P930L | Missense Mutation (SNP) | VAF 42/262 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as rs924720161; called by muse, mutect2, varscan2
- TRAF7 | c.237del p.I80Sfs*48 | Frame Shift Del (DEL) | VAF 32/153 reads (21%) | catalogued as rs774508592; called by mutect2, pindel, varscan2
- TRAPPC8 | c.3935C>T p.T1312M | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.261); catalogued as rs369850024; called by muse, mutect2, varscan2
- TRAV2 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs368856104; called by muse, mutect2, varscan2
- TRIM35 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 40/322 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.388); catalogued as rs748533193, COSV59524520; called by muse, mutect2, varscan2
- TRIP11 | c.3800A>G p.Y1267C | Missense Mutation (SNP) | VAF 94/271 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs765559007; called by muse, mutect2, varscan2
- TRMT9B | c.306C>G p.F102L | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV71600837; called by muse, mutect2, varscan2
- TRPC6 | c.1128del p.K376Nfs*3 | Frame Shift Del (DEL) | VAF 35/181 reads (19%) | catalogued as COSV60250864; called by mutect2, pindel, varscan2
- TRPM2 | c.2492C>T p.A831V | Missense Mutation (SNP) | VAF 79/458 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs1365087231; called by muse, mutect2, varscan2
- TSSK1B | c.515G>A p.S172N | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200163161; called by muse, mutect2, varscan2
- TSSK2 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as rs138737621; called by muse, mutect2, varscan2
- TTN | c.78752G>A p.G26251D (on ENST00000591111; = p.G18827D on NM_003319.4) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | PolyPhen probably damaging (1); catalogued as COSV100625660; called by muse, mutect2, varscan2
- TUBA1B | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 77/521 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.096); catalogued as COSV60136546; called by muse, mutect2, varscan2
- TYW1 | c.1855G>A p.A619T | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.156); catalogued as COSV62751331; called by muse, mutect2, varscan2
- UBE2J2 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 36/247 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as rs771675327, COSV59571516; called by muse, mutect2, varscan2
- UBTD2 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs768061481; called by muse, mutect2, varscan2
- UFL1 | c.1341del p.V448Sfs*39 | Frame Shift Del (DEL) | VAF 9/53 reads (17%) | catalogued as CM142660; called by mutect2, pindel, varscan2
- UGT1A7 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 35/294 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as rs765046704, COSV100693164; called by muse, mutect2, varscan2
- UIMC1 | c.330G>C p.L110F | Missense Mutation (SNP) | VAF 29/250 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65893737; called by muse, mutect2, varscan2
- UMODL1 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 79/511 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs756749467, COSV68578469; called by muse, mutect2, varscan2
- UNC79 | c.6248G>A p.R2083H (on ENST00000393151 / NM_001346218.2; = p.R1906H on NM_020818.5) | Missense Mutation (SNP) | VAF 68/200 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747829774, COSV56375334; called by muse, mutect2, varscan2
- UPK3B | c.599C>T p.A200V (on ENST00000257632; = p.A145V on NM_001347684.2) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.535); catalogued as rs1453870331; called by muse, mutect2, varscan2
- URGCP | c.424G>A p.A142T (on ENST00000453200 / NM_001077663.3; = p.A133T on NM_017920.4) | Missense Mutation (SNP) | VAF 51/318 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs371922619; called by muse, mutect2, varscan2
- USP31 | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.026); catalogued as rs1430919532; called by muse, mutect2, varscan2
- VAC14 | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as rs751118482; called by muse, mutect2, varscan2
- VARS1 | c.3772G>A p.A1258T | Missense Mutation (SNP) | VAF 30/298 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.058); catalogued as rs1330119096, COSV63304669, COSV63304929; called by muse, mutect2, varscan2
- VPS53 | c.2371C>T p.R791C | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1188509631; called by muse, mutect2, varscan2
- VRTN | c.1428G>C p.K476N | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.441); catalogued as COSV56443299; called by muse, mutect2
- WBP1 | c.552del p.H185Ifs*10 | Frame Shift Del (DEL) | VAF 28/199 reads (14%) | catalogued as rs773064295, COSV51967888; called by mutect2, pindel, varscan2
- WDFY4 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 67/357 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.026); catalogued as rs200560672; called by muse, mutect2, varscan2
- WDPCP | c.1576G>A p.A526T | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.041); catalogued as rs534102944, COSV99703720; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR17 | c.2196A>C p.K732N | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV54569338; called by muse, mutect2, varscan2
- WDR49 | c.1594G>A p.D532N (on ENST00000308378 / NM_001366158.1; = p.D873N on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1455497358; called by muse, mutect2, varscan2
- WDR86 | c.528G>T p.K176N | Missense Mutation (SNP) | VAF 66/387 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57838545; called by muse, mutect2, varscan2
- WHRN | c.1516C>T p.R506W | Missense Mutation (SNP) | VAF 34/244 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.077); catalogued as rs1311654091; called by muse, mutect2, varscan2
- WIPI1 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.206); catalogued as rs753126011, COSV50929746; called by muse, mutect2
- WNT9A | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 49/276 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as COSV99688379; called by muse, varscan2
- WNT9A | c.500dup p.C168Lfs*6 | Frame Shift Ins (INS) | VAF 63/348 reads (18%) | catalogued as rs779992922, COSV55293438; called by mutect2, varscan2
- WSB2 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs550650687, COSV59573597; called by muse, mutect2, varscan2
- YTHDC1 | c.482G>A p.R161K | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.745); catalogued as rs1395785011; called by muse, mutect2, varscan2
- ZBP1 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 65/394 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762511482; called by muse, mutect2, varscan2
- ZC3HAV1 | c.435del p.F145Lfs*49 | Frame Shift Del (DEL) | VAF 13/84 reads (15%) | catalogued as rs1363033923; called by mutect2, pindel, varscan2
- ZCCHC14 | c.712A>G p.I238V (on ENST00000268616; = p.I375V on NM_015144.3) | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.891); catalogued as rs757510774; called by muse, mutect2, varscan2
- ZFP28 | c.64dup p.R22Pfs*73 | Frame Shift Ins (INS) | VAF 27/187 reads (14%) | catalogued as rs905249572; called by mutect2, pindel, varscan2
- ZNF106 | c.4876C>T p.R1626* | Nonsense Mutation (SNP) | VAF 35/211 reads (17%) | catalogued as rs371478902, COSV55515865; called by muse, mutect2, varscan2
- ZNF141 | c.1216C>T p.R406W | Missense Mutation (SNP) | VAF 30/249 reads (12%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.864); catalogued as rs782182014; called by muse, mutect2, varscan2
- ZNF142 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.399); catalogued as COSV63720166; called by muse, mutect2, varscan2
- ZNF19 | c.12G>A p.M4I | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs754349380, COSV55508453; called by muse, mutect2, varscan2
- ZNF292 | c.4502G>A p.S1501N | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs753343902, COSV100370300; called by muse, mutect2, varscan2
- ZNF518A | c.2785del p.T929Lfs*2 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | catalogued as rs781933025; called by mutect2, varscan2
- ZNF518A | c.2899C>A p.P967T | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.311); catalogued as rs369438287; called by muse, mutect2, varscan2
- ZNF566 | c.923A>G p.E308G | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67573137; called by muse, mutect2
- ZNF594 | c.1465C>T p.Q489* | Nonsense Mutation (SNP) | VAF 41/256 reads (16%) | catalogued as COSV68384739; called by muse, varscan2
- ZNF717 | c.1606G>A p.A536T | Missense Mutation (SNP) | VAF 27/210 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1280458086; called by muse, mutect2, varscan2
- ZNF773 | c.271C>T p.Q91* | Nonsense Mutation (SNP) | VAF 12/73 reads (16%) | catalogued as rs750281093; called by mutect2, varscan2
- ZNF786 | c.877del p.E293Rfs*88 | Frame Shift Del (DEL) | VAF 20/108 reads (19%) | catalogued as rs1341075761; called by mutect2, pindel, varscan2
- ZNF837 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.703); catalogued as rs1404435420, COSV69893124; called by muse, mutect2, varscan2
- ABCB9 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 125/676 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ABCC11 | c.2728T>C p.F910L | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- ABCC8 | c.4669C>T p.L1557F | Missense Mutation (SNP) | VAF 78/468 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- ACAP2 | c.1021C>T p.L341F | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ACER3 | c.62G>A p.C21Y | Missense Mutation (SNP) | VAF 37/286 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ACIN1 | c.352dup p.H118Pfs*12 | Frame Shift Ins (INS) | VAF 35/225 reads (16%) | called by mutect2, pindel, varscan2
- ACKR1 | c.628C>A p.H210N | Missense Mutation (SNP) | VAF 51/336 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ACOT7 | c.275G>A p.C92Y (on ENST00000377855 / NM_181864.3; = p.C82Y on NM_007274.4) | Missense Mutation (SNP) | VAF 56/288 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- ACOT8 | c.866G>T p.G289V | Missense Mutation (SNP) | VAF 37/238 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACTN3 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 36/284 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ADAD1 | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADAMTS10 | c.2585C>G p.A862G | Missense Mutation (SNP) | VAF 46/216 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- ADAMTS13 | c.2296C>A p.P766T | Missense Mutation (SNP) | VAF 82/388 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADAMTS18 | c.3317dup p.L1106Ffs*68 | Frame Shift Ins (INS) | VAF 46/310 reads (15%) | called by mutect2, pindel, varscan2
- ADAMTS6 | c.2218A>G p.R740G | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- ADCY2 | c.1971del p.A658Pfs*9 | Frame Shift Del (DEL) | VAF 19/108 reads (18%) | called by mutect2, pindel, varscan2
- ADGRF3 | c.1376del p.G459Afs*2 (on ENST00000311519 / NM_001145168.1; = p.G260Afs*2 on NM_153835.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 49/284 reads (17%) | called by mutect2, pindel, varscan2
- ADGRV1 | c.11815G>T p.V3939F | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.172); called by muse, mutect2
- ADGRV1 | c.15022del p.S5008Pfs*8 | Frame Shift Del (DEL) | VAF 12/60 reads (20%) | called by mutect2, pindel
- ADK | c.29C>A p.P10H | Missense Mutation (SNP) | VAF 54/336 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- ADRA1B | c.978del p.D327Tfs*88 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | called by mutect2, pindel, varscan2
- AHNAK | c.9064del p.M3022Cfs*4 | Frame Shift Del (DEL) | VAF 67/403 reads (17%) | called by mutect2, pindel, varscan2
- AHNAK2 | c.5168A>G p.N1723S | Missense Mutation (SNP) | VAF 134/755 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AICDA | c.50del p.N17Mfs*16 | Frame Shift Del (DEL) | VAF 45/239 reads (19%) | called by mutect2, pindel, varscan2
- AJUBA | c.35dup p.E13Gfs*9 | Frame Shift Ins (INS) | VAF 104/369 reads (28%) | called by mutect2, pindel, varscan2
- AKR1C4 | c.949T>C p.Y317H | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.228); called by muse, mutect2
- AKR7A3 | c.996G>T p.*332Yext*22 | Nonstop Mutation (SNP) | VAF 16/418 reads (4%) | called by muse, mutect2
- AL669918.1 | c.2006C>G p.S669* | Nonsense Mutation (SNP) | VAF 30/155 reads (19%) | called by muse, mutect2, varscan2
- ALDH16A1 | c.1924G>T p.G642C | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ALKBH4 | c.287C>A p.P96H | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- ANK2 | c.3809dup p.A1271Cfs*17 | Frame Shift Ins (INS) | VAF 34/219 reads (16%) | called by mutect2, pindel, varscan2
- ANKRD30B | c.578C>A p.T193K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKRD65 | c.149G>A p.W50* | Nonsense Mutation (SNP) | VAF 30/224 reads (13%) | called by muse, varscan2
- ANO9 | c.1096G>T p.A366S | Missense Mutation (SNP) | VAF 67/392 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- AOC3 | c.1318del p.L440Cfs*46 | Frame Shift Del (DEL) | VAF 69/390 reads (18%) | called by mutect2, pindel, varscan2
- AP4E1 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- APOB | c.2516C>G p.P839R | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARFGEF3 | c.5470G>A p.A1824T | Missense Mutation (SNP) | VAF 55/303 reads (18%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ARHGAP29 | c.1806G>C p.K602N | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- ARHGEF17 | c.518del p.P173Lfs*16 | Frame Shift Del (DEL) | VAF 36/181 reads (20%) | called by mutect2, pindel, varscan2
- ARHGEF17 | c.1850del p.P617Lfs*10 | Frame Shift Del (DEL) | VAF 62/412 reads (15%) | called by mutect2, pindel, varscan2
- ARHGEF25 | c.588del p.E197Rfs*33 | Frame Shift Del (DEL) | VAF 20/197 reads (10%) | called by mutect2, pindel
- ARHGEF40 | c.4459del p.H1487Tfs*15 | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | called by mutect2, pindel, varscan2
- ARID1B | c.2162del p.G721Afs*11 | Frame Shift Del (DEL) | VAF 47/295 reads (16%) | called by mutect2, pindel, varscan2
- ASAP2 | c.2564G>A p.S855N | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ASIC2 | c.1420A>G p.S474G | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2
- ATF7 | c.975G>T p.Q325H (on ENST00000548446 / NM_001366555.2; = p.Q314H on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- ATMIN | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ATOH7 | c.277A>G p.T93A | Missense Mutation (SNP) | VAF 57/382 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- ATP11A | c.780G>C p.E260D | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ATXN7 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- B4GALNT4 | c.2150A>G p.E717G | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- BAZ2A | c.5425A>G p.M1809V | Missense Mutation (SNP) | VAF 21/212 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- BBOX1 | c.554A>G p.D185G | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); called by muse, mutect2
- BCAR1 | c.1576G>A p.V526M | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- BCL11B | c.1457G>A p.G486D (on ENST00000357195 / NM_001282237.2; = p.G415D on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 93/479 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- BCORL1 | c.1947del p.V650Cfs*45 | Frame Shift Del (DEL) | VAF 41/145 reads (28%) | called by mutect2, pindel, varscan2
- BET1 | c.126A>C p.K42N | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BICRA | c.3967C>T p.H1323Y | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- BRD9 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.94); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- BRIP1 | c.832A>G p.S278G | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BSN | c.5041G>A p.D1681N | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BTN3A1 | c.1144T>C p.Y382H | Missense Mutation (SNP) | VAF 36/259 reads (14%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- BZW1 | c.854del p.N285Tfs*11 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | called by mutect2, varscan2
- C10orf71 | c.836C>T p.S279L | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- C14orf93 | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 58/298 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- C16orf92 | c.51-1G>T p.X17_splice | Splice Site (SNP) | VAF 26/142 reads (18%) | called by muse, mutect2, varscan2
- C17orf50 | c.286C>T p.L96F | Missense Mutation (SNP) | VAF 60/311 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- C21orf91 | c.867G>A p.M289I (on ENST00000284881 / NM_001100420.2; = p.M288I on NM_017447.4) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2
- C2orf42 | c.1348C>A p.P450T | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- CAD | c.2400+2T>C p.X800_splice | Splice Site (SNP) | VAF 40/182 reads (22%) | called by muse, mutect2, varscan2
- CAPN13 | c.791del p.G264Afs*87 | Frame Shift Del (DEL) | VAF 14/92 reads (15%) | called by mutect2, pindel, varscan2
- CAPN14 | c.1586del p.K529Sfs*14 | Frame Shift Del (DEL) | VAF 8/60 reads (13%) | called by mutect2, pindel, varscan2
- CAPN7 | c.2428A>G p.T810A | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2
- CARMIL3 | c.3200A>G p.D1067G | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.019); called by muse, varscan2
- CASTOR2 | c.748T>G p.F250V | Missense Mutation (SNP) | VAF 18/529 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- CAV1 | c.446C>A p.S149Y | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CCDC130 | c.400+8C>T | Splice Region (SNP) | VAF 37/195 reads (19%) | called by muse, mutect2, varscan2
- CCDC198 | c.370G>T p.A124S | Missense Mutation (SNP) | VAF 33/243 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- CCDC82 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 44/278 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.911); called by muse, varscan2
- CCDC88B | c.1486C>T p.P496S | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC89 | c.953C>A p.A318E | Missense Mutation (SNP) | VAF 43/249 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- CCKBR | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 38/273 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- CCM2 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 36/263 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CCNA1 | c.1076T>A p.V359D | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCNG1 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- CCR9 | c.710T>C p.I237T (on ENST00000357632 / NM_031200.3; = p.I225T on NM_006641.4) | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CD14 | c.1112C>G p.A371G | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD248 | c.1295dup p.L433Afs*47 | Frame Shift Ins (INS) | VAF 15/77 reads (19%) | called by mutect2, pindel, varscan2
- CDH15 | c.1429A>G p.N477D | Missense Mutation (SNP) | VAF 61/347 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH4 | c.1220A>C p.E407A | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- CDHR5 | c.1342G>C p.E448Q | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CDK16 | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 129/373 reads (35%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- CDK17 | c.1425T>G p.S475R | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- CDKL2 | c.836C>A p.A279D | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CDRT1 | c.1756C>T p.H586Y | Missense Mutation (SNP) | VAF 39/326 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- CDX2 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- CENPF | c.415C>A p.L139M | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- CEP162 | c.2761del p.I921Ffs*15 | Frame Shift Del (DEL) | VAF 28/117 reads (24%) | called by mutect2, pindel, varscan2
- CEP170 | c.3678A>G p.V1226= | Splice Region (SNP) | VAF 13/75 reads (17%) | called by muse, varscan2
- CFAP61 | c.2956A>G p.R986G | Missense Mutation (SNP) | VAF 39/236 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- CFAP74 | c.867G>T p.K289N | Missense Mutation (SNP) | VAF 52/338 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CFTR | c.4053G>T p.K1351N | Missense Mutation (SNP) | VAF 41/234 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- CHRM2 | c.1071G>T p.K357N | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CHRNA2 | c.1557_1558del p.F520Sfs*24 | Frame Shift Del (DEL) | VAF 30/290 reads (10%) | called by pindel, varscan2
- CLCA4 | c.1820T>C p.F607S | Missense Mutation (SNP) | VAF 44/236 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CLCN6 | c.439del p.V148Ffs*19 | Frame Shift Del (DEL) | VAF 31/200 reads (16%) | called by mutect2, pindel, varscan2
- CLCN7 | c.1331del p.G444Afs*32 | Frame Shift Del (DEL) | VAF 55/342 reads (16%) | called by mutect2, pindel, varscan2
- CLIC5 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL14A1 | c.1251A>T p.E417D | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- COL27A1 | c.1356del p.K452Nfs*6 | Frame Shift Del (DEL) | VAF 24/165 reads (15%) | called by mutect2, pindel, varscan2
- COL6A6 | c.1199A>C p.N400T | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- COP1 | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- CPSF2 | c.1697G>A p.G566D | Missense Mutation (SNP) | VAF 48/308 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CPSF4 | c.595A>G p.R199G | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRAMP1 | c.812A>G p.E271G | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CRTC3 | c.316del p.L106Sfs*48 | Frame Shift Del (DEL) | VAF 36/246 reads (15%) | called by mutect2, pindel, varscan2
- CTBP1 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 78/379 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- CTDSPL2 | c.1101G>T p.K367N | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- CTTNBP2 | c.1828C>A p.Q610K | Missense Mutation (SNP) | VAF 44/236 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CUBN | c.422G>T p.C141F | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CXXC4 | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 43/260 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYC1 | c.772+1G>A p.X258_splice | Splice Site (SNP) | VAF 19/113 reads (17%) | called by muse, mutect2, varscan2
- DAGLB | c.1261_1263del p.N421del | In Frame Del (DEL) | VAF 32/233 reads (14%) | called by mutect2, pindel, varscan2
- DAPK1 | c.731C>A p.T244N | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DCHS1 | c.4453G>A p.A1485T | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DCUN1D1 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); called by muse, varscan2
- DDR1 | c.1797del p.R602Efs*51 (on ENST00000324771; = p.R565Efs*51 on NM_001954.4) | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | called by mutect2, pindel, varscan2
- DDX3Y | c.872C>T p.S291F | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDX43 | c.819G>A p.W273* | Nonsense Mutation (SNP) | VAF 13/72 reads (18%) | called by muse, mutect2, varscan2
- DEAF1 | c.996C>A p.T332= | Splice Region (SNP) | VAF 96/541 reads (18%) | called by muse, mutect2, varscan2
- DEFB129 | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 5/77 reads (6%) | called by muse, mutect2
- DLL1 | c.1618G>A p.G540S | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH3 | c.9161G>T p.W3054L | Missense Mutation (SNP) | VAF 44/248 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH7 | c.11339G>A p.S3780N | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH8 | c.2857C>A p.L953M | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2
- DNHD1 | c.3034A>G p.T1012A | Missense Mutation (SNP) | VAF 42/321 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- DOCK5 | c.4704+8T>C | Splice Region (SNP) | VAF 48/331 reads (15%) | called by muse, mutect2, varscan2
- DOCK5 | c.4713del p.F1571Lfs*19 | Frame Shift Del (DEL) | VAF 11/90 reads (12%) | called by mutect2, pindel, varscan2
- DYNAP | c.274C>A p.L92I (on ENST00000321600; = p.L66I on NM_173629.3) | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- DYSF | c.5618T>C p.F1873S | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- DZIP1 | c.1255G>T p.E419* | Nonsense Mutation (SNP) | VAF 19/113 reads (17%) | called by muse, mutect2, varscan2
- E2F7 | c.895C>A p.L299I | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- EEF1AKMT4-ECE2 | c.1979A>G p.D660G | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); called by muse, mutect2
- EFEMP1 | c.347del p.G116Vfs*59 | Frame Shift Del (DEL) | VAF 72/554 reads (13%) | called by mutect2, pindel, varscan2
- EGFL6 | c.1632T>A p.C544* | Nonsense Mutation (SNP) | VAF 23/66 reads (35%) | called by muse, mutect2, varscan2
- EGFLAM | c.1480A>G p.T494A | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- EHBP1L1 | c.3101C>A p.P1034H | Missense Mutation (SNP) | VAF 37/232 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- EHBP1L1 | c.3649G>A p.A1217T | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EHD1 | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 77/439 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- EIF2AK2 | c.121T>C p.F41L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EIF4A2 | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- EIF4G3 | c.247del p.Q83Nfs*43 | Frame Shift Del (DEL) | VAF 8/92 reads (9%) | called by mutect2, varscan2
- EP300 | c.1151C>G p.S384* | Nonsense Mutation (SNP) | VAF 24/147 reads (16%) | called by muse, mutect2, varscan2
- EP400 | c.4598del p.P1533Rfs*35 | Frame Shift Del (DEL) | VAF 38/271 reads (14%) | called by mutect2, pindel, varscan2
- EPB41L4A | c.1623_1625del p.R542del | In Frame Del (DEL) | VAF 9/79 reads (11%) | called by mutect2, pindel, varscan2
- EPG5 | c.2523A>C p.R841S | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.164); called by muse, varscan2
- EPHB6 | c.1972G>T p.A658S | Missense Mutation (SNP) | VAF 72/422 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- EPN3 | c.1780G>T p.A594S | Missense Mutation (SNP) | VAF 86/537 reads (16%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- EPRS1 | c.4403A>G p.E1468G | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ERVFRD-1 | c.472T>C p.Y158H | Missense Mutation (SNP) | VAF 29/273 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- ERVW-1 | c.887dup p.M297Yfs*6 | Frame Shift Ins (INS) | VAF 5/39 reads (13%) | called by mutect2, pindel
- EXOC1 | c.2259del p.E754Kfs*18 | Frame Shift Del (DEL) | VAF 22/95 reads (23%) | called by mutect2, varscan2
- FAM186A | c.2794del p.M932* | Frame Shift Del (DEL) | VAF 32/253 reads (13%) | called by mutect2, pindel, varscan2
- FAM217B | c.611del p.G204Afs*15 | Frame Shift Del (DEL) | VAF 35/199 reads (18%) | called by mutect2, pindel, varscan2
- FAM53B | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 43/201 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FAM83E | c.674G>T p.S225I | Missense Mutation (SNP) | VAF 30/276 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, varscan2
- FAT2 | c.10124del p.K3375Rfs*20 | Frame Shift Del (DEL) | VAF 31/181 reads (17%) | called by mutect2, pindel, varscan2
- FBLN2 | c.686del p.P229Qfs*45 | Frame Shift Del (DEL) | VAF 22/121 reads (18%) | called by mutect2, pindel, varscan2
- FBN1 | c.8608C>T p.L2870F | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FBXO30 | c.641T>C p.V214A | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT tolerated (0.88); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FCHO1 | c.2648-1G>T p.X883_splice | Splice Site (SNP) | VAF 19/118 reads (16%) | called by muse, varscan2
- FERMT3 | c.1392C>A p.S464R (on ENST00000279227 / NM_178443.3; = p.S460R on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 122/670 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FGL1 | c.443T>A p.V148D | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.018); called by muse, mutect2
- FLG2 | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 51/325 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- FLNB | c.2911del p.A971Qfs*9 | Frame Shift Del (DEL) | VAF 58/335 reads (17%) | called by mutect2, pindel, varscan2
- FMN2 | c.2317del p.A773Lfs*15 | Frame Shift Del (DEL) | VAF 46/299 reads (15%) | called by mutect2, pindel, varscan2
- FMNL1 | c.2918A>G p.Y973C | Missense Mutation (SNP) | VAF 54/318 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FMNL3 | c.894G>T p.K298N | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FOLH1 | c.647del p.N216Mfs*24 | Frame Shift Del (DEL) | VAF 7/42 reads (17%) | called by mutect2, varscan2
- FOLR3 | c.494-1G>T p.X165_splice | Splice Site (SNP) | VAF 36/175 reads (21%) | called by muse, mutect2, varscan2
- FRY | c.692T>C p.V231A | Missense Mutation (SNP) | VAF 75/445 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- FRYL | c.8272A>C p.T2758P | Missense Mutation (SNP) | VAF 30/226 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- FRYL | c.759C>G p.F253L | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- FXR1 | c.1829del p.N610Tfs*8 | Frame Shift Del (DEL) | VAF 13/89 reads (15%) | called by mutect2, pindel, varscan2
- FZD7 | c.512del p.G171Afs*72 | Frame Shift Del (DEL) | VAF 77/434 reads (18%) | called by mutect2, pindel, varscan2
- FZD7 | c.1312T>C p.S438P | Missense Mutation (SNP) | VAF 93/569 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- FZD8 | c.1046del p.G349Afs*67 | Frame Shift Del (DEL) | VAF 7/40 reads (18%) | called by mutect2, pindel, varscan2
- GABRA2 | c.1244G>T p.S415I | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GABRG2 | c.481C>G p.H161D | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GAK | c.3872T>A p.I1291N | Missense Mutation (SNP) | VAF 44/283 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GARNL3 | c.145-1G>A p.X49_splice | Splice Site (SNP) | VAF 18/112 reads (16%) | called by muse, mutect2, varscan2
- GCGR | c.1207C>T p.L403F | Missense Mutation (SNP) | VAF 41/272 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- GCH1 | c.259del p.Q87Sfs*31 | Frame Shift Del (DEL) | VAF 74/465 reads (16%) | called by mutect2, pindel, varscan2
- GCSAML | c.140-4C>A | Splice Region (SNP) | VAF 14/88 reads (16%) | called by muse, varscan2
- GDPD5 | c.706del p.A236Pfs*80 | Frame Shift Del (DEL) | VAF 15/87 reads (17%) | called by mutect2, pindel, varscan2
- GDPD5 | c.453G>T p.E151D | Missense Mutation (SNP) | VAF 36/265 reads (14%) | SIFT tolerated (0.88); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GIMAP4 | c.415A>G p.K139E | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- GJD2 | c.413del p.G138Afs*13 | Frame Shift Del (DEL) | VAF 36/217 reads (17%) | called by mutect2, pindel, varscan2
- GLRA3 | c.143A>T p.D48V | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GOLGA8J | c.1754C>A p.A585D | Missense Mutation (SNP) | VAF 24/201 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); called by mutect2, varscan2
- GPC4 | c.702G>T p.K234N | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- GPR158 | c.1511A>G p.H504R | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- GREB1L | c.4600C>A p.L1534I | Missense Mutation (SNP) | VAF 20/376 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.168); called by muse, mutect2
- GRHL2 | c.517C>T p.H173Y | Missense Mutation (SNP) | VAF 68/553 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- GRIN2A | c.171del p.E58Sfs*10 | Frame Shift Del (DEL) | VAF 103/584 reads (18%) | called by mutect2, pindel, varscan2
- GRK3 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 54/410 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.96); called by muse, varscan2
- GRM2 | c.276C>A p.C92* | Nonsense Mutation (SNP) | VAF 43/174 reads (25%) | called by muse, mutect2, varscan2
- GSDMB | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 37/215 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.063); called by muse, mutect2, varscan2
1,002 further variants in this file (423 protein-altering or splice-affecting, 329 silent, 250 other) are not listed here.
